Somatic mutation profile of tumor specimen C3L-06015-05 (aliquot CPT0360520006) from CPTAC case C3L-06015, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 85.1 years (31,072 days).
Specimen C3L-06015-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b42ef00f-1f1c-4c39-8e1b-78e19827a6af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06015-31 (Blood Derived Normal), aliquot CPT0360580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2985ce4d-1aa0-407e-bdd4-d42fd770d821

The open-access MAF lists 103 somatic variants for this specimen: 79 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 21, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 156/399 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs121913513, CM133722, COSV55386593, COSV55412340; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- MMAA | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 149/489 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150376474, COSV55582009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 136/414 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs755149170, COSV59389635; called by muse, varscan2
- ARFGEF1 | c.2648C>G p.S883* | Nonsense Mutation (SNP) | VAF 115/467 reads (25%) | catalogued as COSV99145043; called by muse, mutect2, varscan2
- ATP6V0A4 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 284/416 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1307634065; called by muse, mutect2, varscan2
- ATXN7 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 213/603 reads (35%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.926); catalogued as rs751858038, COSV55750017; called by muse, mutect2, varscan2
- CAPSL | c.264T>A p.D88E | Missense Mutation (SNP) | VAF 17/441 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV68439507; called by muse, mutect2
- CBL | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs933954615; called by muse, mutect2, varscan2
- COL27A1 | c.4414G>T p.G1472W | Missense Mutation (SNP) | VAF 93/462 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61922147; called by muse, mutect2, varscan2
- EIF3E | c.972_974del p.F324del | In Frame Del (DEL) | VAF 96/394 reads (24%) | catalogued as rs1313963158; called by pindel, varscan2
- ERF | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 138/406 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99724876; called by muse, mutect2, varscan2
- FAM200B | c.1904T>C p.M635T | Missense Mutation (SNP) | VAF 146/494 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs371969327; called by muse, mutect2, varscan2
- FBXO9 | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 147/473 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs201077426; called by muse, mutect2, varscan2
- GRIN2A | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1415214536, COSV58055967; called by muse, mutect2, varscan2
- IGSF9 | c.2224G>A p.G742R (on ENST00000368094 / NM_001135050.2; = p.G726R on NM_020789.4) | Missense Mutation (SNP) | VAF 72/810 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1372763087; called by muse, mutect2
- KBTBD8 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 166/468 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs765704147; called by muse, mutect2, varscan2
- KIF2B | c.1865A>C p.N622T | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99275174; called by muse, mutect2
- KIT | c.1890T>A p.H630Q | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761703470, CM950715; called by muse, mutect2, varscan2
- MAP4K4 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 145/498 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as rs762381643; called by muse, mutect2, varscan2
- MED23 | c.1623C>G p.H541Q | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63431489; called by muse, mutect2, varscan2
- NEB | c.12731T>C p.V4244A | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as COSV99413839; called by muse, mutect2, varscan2
- NKX2-5 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 172/541 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100234910; called by muse, varscan2
- OR2T2 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 168/1800 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749616270, COSV61617945; called by muse, mutect2
- PCBP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 47/734 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2
- PITPNB | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 92/452 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as rs1310641123; called by muse, mutect2, varscan2
- PPP1R16A | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 251/847 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs760848217; called by muse, mutect2, varscan2
- PRSS3 | c.103G>A p.G35S (on ENST00000361005 / NM_007343.4; = p.G143S on NM_002771.3) | Missense Mutation (SNP) | VAF 157/556 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753580774, COSV61560870; called by muse, mutect2, varscan2
- PTPN23 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 309/877 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs763104053, COSV55546400; called by muse, mutect2, varscan2
- PTPRE | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as rs763484663; called by muse, mutect2, varscan2
- PTTG1 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 103/365 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.021); catalogued as rs762752660; called by muse, mutect2, varscan2
- SLC16A1 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 227/481 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs957147113; called by muse, mutect2, varscan2
- TAS2R60 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 13/498 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60330094; called by muse, mutect2
- TLE6 | c.1277G>A p.S426N (on ENST00000246112 / NM_001143986.2; = p.S303N on NM_024760.3) | Missense Mutation (SNP) | VAF 28/423 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs376939088; called by muse, mutect2
- XPNPEP3 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 141/747 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64028926; called by muse, mutect2, varscan2
- ADAMTS13 | c.3458C>A p.T1153N | Missense Mutation (SNP) | VAF 176/361 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AK8 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.119); called by muse, mutect2
- BTNL9 | c.275T>A p.L92H | Missense Mutation (SNP) | VAF 175/501 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CCDC93 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 138/489 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEPT1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 154/727 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP221 | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 121/405 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CFAP73 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 27/562 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2
- CR2 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DHCR24 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- DMD | c.2320T>A p.F774I | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH2 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 142/372 reads (38%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAVL4 | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 21/476 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2
- FSTL1 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 150/462 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HMCN2 | c.13729G>C p.V4577L | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2
- IGHA2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.36); called by muse, mutect2
- ITPR3 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 135/580 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- KCNH5 | c.2621G>C p.R874P | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRT71 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); called by muse, mutect2
- LMTK3 | c.2632A>G p.K878E | Missense Mutation (SNP) | VAF 169/606 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGED2 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAU2 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEI4 | c.769T>A p.F257I | Missense Mutation (SNP) | VAF 89/157 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- MGAT4A | c.422T>G p.I141S | Missense Mutation (SNP) | VAF 114/352 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAN | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NCSTN | c.1352A>G p.K451R | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKX6-2 | c.570C>G p.S190R | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4C13 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); called by muse, mutect2
- PAPSS2 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 126/424 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAX1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 33/596 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- PCDHA11 | c.1307C>G p.A436G | Missense Mutation (SNP) | VAF 18/558 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); called by muse, mutect2
- POMGNT2 | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- RANBP2 | c.3337G>C p.E1113Q | Missense Mutation (SNP) | VAF 14/500 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2
- RTF1 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A1 | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPATA19 | c.414T>A p.D138E | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPOCK3 | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SSR1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 111/474 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TM2D1 | c.259A>G p.N87D | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- TOGARAM1 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 145/413 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TTN | c.86663G>A p.G28888D (on ENST00000591111; = p.G21464D on NM_003319.4) | Missense Mutation (SNP) | VAF 32/318 reads (10%) | PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- USP9X | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2
- UTP15 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- WDR26 | c.675G>T p.E225D (on ENST00000414423 / NM_001379403.1; = p.E125D on NM_025160.7) | Missense Mutation (SNP) | VAF 119/552 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ZNF790 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 148/416 reads (36%) | called by mutect2, varscan2
- ZWILCH | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 114/307 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC1 | c.564G>C p.L188= | Silent (SNP) | VAF 98/393 reads (25%) | called by muse, mutect2, varscan2
- APLF | c.552A>G p.R184= | Silent (SNP) | VAF 114/408 reads (28%) | called by muse, mutect2, varscan2
- BLM | c.684A>C p.S228= | Silent (SNP) | VAF 158/460 reads (34%) | called by muse, mutect2, varscan2
- CD300A | c.462T>C p.T154= | Silent (SNP) | VAF 170/529 reads (32%) | called by muse, mutect2, varscan2
- CENPC | c.1638A>G p.V546= | Silent (SNP) | VAF 64/232 reads (28%) | called by muse, mutect2, varscan2
- COL6A2 | c.2847C>T p.D949= | Silent (SNP) | VAF 63/407 reads (15%) | catalogued as rs369129061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.1758G>A p.K586= | Silent (SNP) | VAF 125/365 reads (34%) | called by muse, mutect2, varscan2
- EYA1 | c.375C>G p.A125= | Silent (SNP) | VAF 126/596 reads (21%) | called by muse, mutect2, varscan2
- FKBP1C | c.84C>T p.T28= | Silent (SNP) | VAF 161/727 reads (22%) | catalogued as rs561159358; called by muse, mutect2, varscan2
- GPX4 | c.45C>A p.L15= | Silent (SNP) | VAF 184/597 reads (31%) | catalogued as rs544230793; called by muse, mutect2
- IGSF10 | c.5586G>A p.L1862= | Silent (SNP) | VAF 121/346 reads (35%) | called by muse, mutect2, varscan2
- IL6ST | c.1191A>G p.L397= | Silent (SNP) | VAF 154/438 reads (35%) | catalogued as rs775774368; called by muse, mutect2, varscan2
- KLHDC7B | c.486G>A p.G162= (on ENST00000395676; = p.G803= on NM_138433.5) | Silent (SNP) | VAF 210/878 reads (24%) | called by muse, mutect2, varscan2
- MYH14 | c.5061G>A p.E1687= | Silent (SNP) | VAF 142/400 reads (36%) | called by muse, mutect2, varscan2
- MYRFL | c.819A>G p.Q273= | Silent (SNP) | VAF 97/337 reads (29%) | catalogued as rs1475374201; called by muse, mutect2, varscan2
- PCDHA2 | c.1671C>T p.D557= | Silent (SNP) | VAF 254/725 reads (35%) | catalogued as COSV65366364; called by muse, mutect2, varscan2
- PLXNA2 | c.5454C>T p.I1818= | Silent (SNP) | VAF 114/387 reads (29%) | catalogued as rs201880117, COSV65437973; called by muse, mutect2, varscan2
- PTCH1 | c.1734G>A p.A578= | Silent (SNP) | VAF 88/233 reads (38%) | catalogued as rs765440424, COSV59493491; ClinVar: likely benign; called by muse, mutect2, varscan2
- RP1 | c.5823T>G p.S1941= | Silent (SNP) | VAF 107/456 reads (23%) | called by muse, mutect2, varscan2
- SLC66A1 | c.579G>C p.V193= | Silent (SNP) | VAF 52/380 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.5178A>G p.P1726= | Silent (SNP) | VAF 102/611 reads (17%) | called by muse, mutect2, varscan2
- C3orf52 | c.*7G>A | 3'UTR (SNP) | VAF 103/309 reads (33%) | catalogued as rs778148012; called by muse, mutect2, varscan2
- PRR12 | c.52-404T>C | Intron (SNP) | VAF 23/625 reads (4%) | called by muse, mutect2
- TERT | c.-57A>C | 5'UTR (SNP) | VAF 145/461 reads (31%) | catalogued as rs878855297, CR131339, COSV57196893; ClinVar: uncertain significance; called by mutect2, varscan2
